Gene-level copy-number profile of tumor specimen RC-B6E3-TBP1-A from RC case RC-B6E3, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants); Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.1 years (24,869 days).
Specimen RC-B6E3-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f215e253-c7f6-4a34-be63-c28a087c10a8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B6E3-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/79d51fcb-5a08-4867-a41f-ef14863b6f98

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 133; copy number 1: 3,855; copy number 2: 49,843; copy number 3: 4,326; copy number 4: 705; copy number 6: 8; copy number 8: 26.

Homozygous deletions (total copy number 0; autosomes only): 130 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.
- chr7:38,256,337–38,311,808, 9 genes (within-gene range 0–1): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr7:142,641,746–142,802,748, 28 genes: TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr9:39,748,514–39,874,562, 3 genes: GLIDR, BX664615.1, BX664615.2.
- chr9:67,791,499–68,229,312, 6 genes: RN7SL787P, SNORA70, AL627230.2, ANKRD20A1, RNU6-368P, AL353608.2.
- chr14:22,168,429–22,552,156, 83 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 34 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:202,614,214–203,782,143, 34 genes, copy number 6–8: MTCO1P17, MTCO2P17, MTATP6P17, MTCO3P17, MTND3P17, MTND4LP17, MTND4P30, MTCO1P54, FAM117B, ICA1L, AC098831.1, KRT8P15, WDR12, CARF, KRT8P52, AC010900.1, NBEAL1, RPL7P14, AC023271.1, AC023271.2, RPL23AP36, RPL12P16, CYP20A1, RN7SL670P, MRPL50P2, ABI2, AC080075.1, RAPH1, AC125238.2, AC125238.1, CD28, KRT18P39, NPM1P33, RNU6-474P.

Autosomal genes at a single copy (total copy number 1): 1,002. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
